Somatic mutation profile of tumor specimen C3N-00307-02 (aliquot CPT0008930006) from CPTAC case C3N-00307, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 70.4 years (25,727 days).
Specimen C3N-00307-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 338b344b-3cea-4ac5-b0a5-ab3c16ee5116.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00307-31 (Blood Derived Normal), aliquot CPT0008970002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7283824a-3990-447d-8f5c-e385bd01b53a

The open-access MAF lists 129 somatic variants for this specimen: 79 protein-altering or splice-affecting, 38 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 38, Intron 8, RNA 3, Nonsense Mutation 2, Splice Site 2, Frame Shift Ins 2, In Frame Del 1, 5'Flank 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 31/235 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRE1 | c.470G>T p.C157F | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV51673049; called by muse, mutect2, varscan2
- AGAP1 | c.1985G>T p.R662L (on ENST00000304032 / NM_001037131.3; = p.R609L on NM_014914.5) | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV58321158; called by muse, mutect2, varscan2
- AKAP17A | c.123G>T p.Q41H | Missense Mutation (SNP) | VAF 63/321 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as rs775775869; called by muse, mutect2, varscan2
- ARHGEF1 | c.1446G>T p.R482S | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100528824; called by muse, mutect2, varscan2
- BCHE | c.1138G>T p.E380* | Nonsense Mutation (SNP) | VAF 8/81 reads (10%) | catalogued as COSV52263488; called by muse, mutect2
- BCR | c.1382C>T p.S461F | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.391); catalogued as rs1227019042; called by muse, mutect2, varscan2
- C9orf43 | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 9/107 reads (8%) | catalogued as rs745469839, COSV55914045; called by muse, mutect2
- CFAP100 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1279820833; called by muse, mutect2
- CHRNA1 | c.1408G>A p.V470M (on ENST00000261007 / NM_001039523.3; = p.V445M on NM_000079.4) | Missense Mutation (SNP) | VAF 44/418 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs372104868; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTROB | c.1579C>T p.R527W | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs778313975, COSV66607864; called by muse, mutect2, varscan2
- CSN1S1 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.078); catalogued as rs749598804; called by muse, mutect2, varscan2
- CSNK1E | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as rs1209553878, COSV63290375; called by muse, mutect2, varscan2
- CST1 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 46/342 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as rs778452912, COSV100494321; called by muse, mutect2, varscan2
- ENG | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 47/268 reads (18%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as rs759102482; called by muse, mutect2, varscan2
- EP300 | c.5809G>C p.E1937Q | Missense Mutation (SNP) | VAF 37/319 reads (12%) | SIFT tolerated (0.96); PolyPhen benign (0.056); catalogued as COSV54343084, COSV54343892; called by muse, mutect2, varscan2
- EPHA4 | c.2396G>A p.R799H | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs914099718, COSV56045888; called by muse, mutect2
- EPX | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs573827983, COSV56595010; called by muse, mutect2, varscan2
- GPR17 | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.961); catalogued as rs755635107, COSV55756400; called by muse, mutect2, varscan2
- GRIK3 | c.593A>G p.Y198C | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.945); catalogued as COSV100902314; called by muse, mutect2, varscan2
- IARS1 | c.3668G>A p.R1223K | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.026); catalogued as rs768914088; called by muse, mutect2, varscan2
- IKZF5 | c.724del p.D242Tfs*11 | Frame Shift Del (DEL) | VAF 18/153 reads (12%) | catalogued as COSV64397980; called by mutect2, pindel, varscan2
- ILVBL | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377459258, COSV54617624; called by muse, mutect2, varscan2
- KIF12 | c.299+1G>T p.X100_splice | Splice Site (SNP) | VAF 11/66 reads (17%) | catalogued as rs1441954059; called by muse, mutect2, varscan2
- MTHFSD | c.838C>T p.P280S (on ENST00000360900 / NM_001159377.2; = p.P279S on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs1486560354; called by muse, mutect2, varscan2
- NXN | c.700G>A p.V234I | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs370296358; called by muse, mutect2, varscan2
- OR10Z1 | c.311C>G p.S104C | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV63523991; called by muse, mutect2
- PCDH8 | c.1993G>A p.G665S | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs1211225317; called by muse, mutect2, varscan2
- PDE1A | c.223C>A p.L75M | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV59529482; called by muse, varscan2
- PRR12 | c.1997C>T p.P666L (on ENST00000615927; = p.P1487L on NM_020719.3) | Missense Mutation (SNP) | VAF 37/331 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as rs373218764; called by muse, mutect2, varscan2
- SBK2 | c.905C>T p.A302V | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.354); catalogued as rs574615556; called by muse, mutect2
- SCD5 | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.727); catalogued as rs757673046; called by muse, mutect2, varscan2
- SLITRK3 | c.2044C>A p.R682S | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as COSV53845401, COSV53849374; called by muse, mutect2, varscan2
- SPIC | c.576G>C p.Q192H | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs1182646336; called by muse, mutect2, varscan2
- STARD9 | c.12628G>T p.V4210L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV51916397; called by muse, mutect2, varscan2
- TMEM242 | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs185691120; called by muse, mutect2, varscan2
- TMEM243 | c.234+1G>T p.X78_splice | Splice Site (SNP) | VAF 22/211 reads (10%) | catalogued as rs759771007; called by muse, mutect2, varscan2
- TRIOBP | c.3136G>T p.A1046S | Missense Mutation (SNP) | VAF 54/407 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); catalogued as rs771454615, COSV100731208; called by muse, mutect2, varscan2
- ZNF423 | c.3085C>T p.R1029C (on ENST00000563137 / NM_001379286.1; = p.R1021C on NM_015069.4) | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs773541714; called by muse, mutect2, varscan2
- APOB | c.1972A>T p.N658Y | Missense Mutation (SNP) | VAF 30/269 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGAP35 | c.578dup p.P194Afs*8 | Frame Shift Ins (INS) | VAF 32/207 reads (15%) | called by mutect2, pindel, varscan2
- C10orf90 | c.314G>A p.G105D | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- C5orf52 | c.36C>G p.D12E | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- CACNA1S | c.4339C>G p.R1447G | Missense Mutation (SNP) | VAF 44/434 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CD47 | c.496A>G p.K166E | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2
- CDX1 | c.229G>T p.G77C | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- CLIP1 | c.21T>A p.S7R | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- CTDSP2 | c.602A>G p.K201R | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- DCTN1 | c.800A>T p.E267V | Missense Mutation (SNP) | VAF 27/302 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); called by muse, mutect2
- DHX9 | c.634A>G p.I212V | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DMBT1 | c.4951G>T p.V1651L (on ENST00000338354 / NM_001377530.1; = p.V894L on NM_004406.3) | Missense Mutation (SNP) | VAF 40/309 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ELAVL3 | c.172C>G p.L58V | Missense Mutation (SNP) | VAF 80/540 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.305); called by muse, varscan2
- EOMES | c.401A>G p.Y134C | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FLG | c.4459G>A p.D1487N | Missense Mutation (SNP) | VAF 59/478 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.088); called by muse, mutect2
- FSHR | c.564T>G p.C188W | Missense Mutation (SNP) | VAF 52/406 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GGN | c.971G>A p.G324D | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- HACE1 | c.1604T>C p.L535S | Missense Mutation (SNP) | VAF 36/242 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HRNR | c.1741T>C p.S581P | Missense Mutation (SNP) | VAF 76/684 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ITPKB | c.745C>A p.Q249K | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MDGA2 | c.1987A>G p.T663A (on ENST00000399232 / NM_001113498.2; = p.T365A on NM_182830.4) | Missense Mutation (SNP) | VAF 31/301 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MELTF | c.2036G>C p.R679P | Missense Mutation (SNP) | VAF 47/445 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- NELL2 | c.1466A>G p.N489S | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PNMA5 | c.583G>C p.E195Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POLM | c.1103G>A p.S368N | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- PRPF18 | c.856G>A p.V286I | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PTGS1 | c.191C>A p.S64Y | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- REEP3 | c.107T>A p.V36D | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPS2 | c.104dup p.R36Pfs*23 | Frame Shift Ins (INS) | VAF 24/159 reads (15%) | called by mutect2, pindel
- SEMA4B | c.452C>G p.T151R | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2
- SLIT1 | c.4564G>T p.V1522L | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SOX3 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.255); called by muse, varscan2
- STXBP5 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TARS2 | c.1802_1810del p.E601_C603del | In Frame Del (DEL) | VAF 22/172 reads (13%) | called by mutect2, pindel
- TCP11X2 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 46/446 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- TELO2 | c.2035-4G>T | Splice Region (SNP) | VAF 34/146 reads (23%) | called by muse, mutect2, varscan2
- TEX19 | c.419A>G p.D140G | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TTC6 | c.767C>A p.P256H | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- TTN | c.46379A>G p.E15460G (on ENST00000591111; = p.E8036G on NM_003319.4) | Missense Mutation (SNP) | VAF 40/432 reads (9%) | PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF383 | c.823A>C p.I275L | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- ADCY4 | c.1965G>C p.L655= | Silent (SNP) | VAF 27/181 reads (15%) | called by muse, mutect2, varscan2
- AKAP13 | c.7323C>T p.G2441= (on ENST00000394518 / NM_007200.5; = p.G2445= on NM_006738.6) | Silent (SNP) | VAF 25/159 reads (16%) | catalogued as COSV100775009; called by muse, mutect2, varscan2
- ALDH7A1 | c.9C>G p.R3= | Silent (SNP) | VAF 36/196 reads (18%) | catalogued as rs770033340, COSV68629776; called by muse, mutect2, varscan2
- ATIC | c.615C>T p.P205= | Silent (SNP) | VAF 31/269 reads (12%) | called by muse, mutect2, varscan2
- CCDC178 | c.1888C>A p.R630= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs775027791, COSV55772123; called by mutect2, varscan2
- CHPF | c.456G>T p.T152= | Silent (SNP) | VAF 16/172 reads (9%) | catalogued as rs894386675; called by muse, mutect2
- CSNK1E | c.594C>T p.S198= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as rs1473926334; called by muse, mutect2, varscan2
- DSCAM | c.867C>A p.G289= | Silent (SNP) | VAF 33/279 reads (12%) | catalogued as COSV101261722; called by muse, mutect2, varscan2
- DUSP9 | c.786C>T p.S262= | Silent (SNP) | VAF 22/80 reads (28%) | called by muse, varscan2
- ESS2 | c.213C>T p.A71= | Silent (SNP) | VAF 60/188 reads (32%) | catalogued as rs759628115, COSV52818772; called by muse, mutect2, varscan2
- EYS | c.1854C>T p.G618= | Silent (SNP) | VAF 14/299 reads (5%) | called by muse, mutect2
- FBF1 | c.1050C>T p.D350= (on ENST00000586717; = p.D364= on NM_001319193.1) | Silent (SNP) | VAF 49/283 reads (17%) | catalogued as rs541926169, COSV59863861; called by muse, mutect2, varscan2
- FBN1 | c.7173C>T p.P2391= | Silent (SNP) | VAF 43/335 reads (13%) | catalogued as COSV57321291; called by muse, mutect2, varscan2
- FCRL2 | c.741T>C p.S247= | Silent (SNP) | VAF 32/286 reads (11%) | catalogued as rs1234295129; called by muse, mutect2, varscan2
- FITM2 | c.567C>T p.T189= | Silent (SNP) | VAF 40/309 reads (13%) | called by muse, mutect2, varscan2
- FOXG1 | c.531C>T p.G177= | Silent (SNP) | VAF 29/227 reads (13%) | called by muse, mutect2, varscan2
- FREM3 | c.5046G>C p.L1682= | Silent (SNP) | VAF 28/224 reads (13%) | called by muse, mutect2, varscan2
- HSPA1L | c.1341C>T p.G447= | Silent (SNP) | VAF 45/178 reads (25%) | catalogued as rs1562340252; called by muse, mutect2, varscan2
- LIMK2 | c.765T>A p.P255= | Silent (SNP) | VAF 18/175 reads (10%) | called by muse, mutect2, varscan2
- LRATD1 | c.630G>C p.T210= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs1410697538; called by muse, mutect2
- LRG1 | c.924C>T p.S308= | Silent (SNP) | VAF 51/249 reads (20%) | catalogued as rs765767495; called by muse, mutect2, varscan2
- MAPK10 | c.777T>C p.Y259= (on ENST00000359221 / NM_001351625.2; = p.Y297= on NM_002753.5) | Silent (SNP) | VAF 8/119 reads (7%) | catalogued as rs1425966894; called by muse, mutect2
- MEPCE | c.1338C>T p.D446= | Silent (SNP) | VAF 17/183 reads (9%) | catalogued as rs763635398, COSV52770009; called by muse, mutect2
- NOS3 | c.1452C>T p.A484= | Silent (SNP) | VAF 15/115 reads (13%) | catalogued as rs772759381; called by muse, mutect2, varscan2
- OR51G2 | c.468T>C p.R156= | Silent (SNP) | VAF 17/95 reads (18%) | called by muse, mutect2, varscan2
- OR5AR1 | c.744C>A p.I248= | Silent (SNP) | VAF 20/124 reads (16%) | catalogued as COSV57254013; called by muse, mutect2, varscan2
- PRR35 | c.1134C>T p.G378= | Silent (SNP) | VAF 11/102 reads (11%) | catalogued as rs1315404847, COSV53462438; called by muse, mutect2, varscan2
- RYR2 | c.5466C>A p.I1822= | Silent (SNP) | VAF 83/403 reads (21%) | called by muse, mutect2, varscan2
- SCN9A | c.2691C>T p.C897= (on ENST00000303354; = p.C886= on NM_002977.3) | Silent (SNP) | VAF 36/367 reads (10%) | catalogued as rs1060504427; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPTBN5 | c.3813C>T p.G1271= | Silent (SNP) | VAF 29/199 reads (15%) | catalogued as rs769680202, COSV100312375; called by muse, mutect2, varscan2
- SYNE2 | c.4287A>C p.L1429= | Silent (SNP) | VAF 15/78 reads (19%) | called by muse, mutect2, varscan2
- TJP1 | c.2073G>C p.L691= | Silent (SNP) | VAF 21/155 reads (14%) | called by muse, mutect2, varscan2
- TMC3 | c.915G>A p.E305= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV100845875; called by mutect2, varscan2
- TMEM213 | c.252C>T p.L84= | Silent (SNP) | VAF 17/180 reads (9%) | called by muse, mutect2, varscan2
- TRIM42 | c.522G>A p.Q174= | Silent (SNP) | VAF 79/212 reads (37%) | catalogued as rs754569531, COSV53886439, COSV99647897; called by muse, mutect2, varscan2
- TRIM75P | c.462A>G p.Q154= | Silent (SNP) | VAF 30/236 reads (13%) | called by muse, mutect2, varscan2
- UBR4 | c.4830G>C p.L1610= | Silent (SNP) | VAF 24/176 reads (14%) | called by muse, mutect2, varscan2
- ZFHX4 | c.4740C>T p.V1580= | Silent (SNP) | VAF 47/206 reads (23%) | catalogued as rs753637211; called by muse, mutect2, varscan2
- AC133561.1 | n.1935G>A | RNA (SNP) | VAF 31/264 reads (12%) | called by muse, mutect2, varscan2
- ASS1 | c.-5-263G>A | Intron (SNP) | VAF 37/349 reads (11%) | catalogued as rs1480154615; called by muse, mutect2, varscan2
- CCDC162P | n.2873G>C | RNA (SNP) | VAF 48/217 reads (22%) | called by muse, mutect2, varscan2
- CNN2 | c.654+99C>G | Intron (SNP) | VAF 12/68 reads (18%) | called by muse, mutect2, varscan2
- EIF2B4 | c.419-33_419-32del | Intron (DEL) | VAF 28/295 reads (9%) | called by mutect2, pindel
- FAM151B | chr5:80488086 C>T | 5'Flank (SNP) | VAF 24/122 reads (20%) | called by muse, mutect2, varscan2
- MACF1 | c.16491+500C>T | Intron (SNP) | VAF 57/417 reads (14%) | catalogued as rs747274833, COSV99247532; called by muse, mutect2, varscan2
- MAPKBP1 | c.327+249C>G | Intron (SNP) | VAF 28/141 reads (20%) | catalogued as rs1431546758; called by muse, mutect2, varscan2
- OR6W1P | n.377C>T | RNA (SNP) | VAF 21/174 reads (12%) | called by muse, mutect2, varscan2
- SMYD3 | c.532-131G>A | Intron (SNP) | VAF 15/161 reads (9%) | called by muse, mutect2
- TANC2 | c.3676+577G>A | Intron (SNP) | VAF 16/182 reads (9%) | catalogued as rs1221624574, COSV67342755; called by muse, mutect2
- ZNF497 | c.-111-940G>T | Intron (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
